Gene-level copy-number profile of tumor specimen HCM-BROD-0254-C49-86M from HCMI case HCM-BROD-0254-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 11.9 years (4,358 days).
Specimen HCM-BROD-0254-C49-86M: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 17.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file abe9a916-e6d6-4ba1-89c0-80e3f3a8db01.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0254-C49-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/8195d12b-716a-4f8d-aef7-1767d72b4167

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 5,456; copy number 3: 21,591; copy number 4: 18,145; copy number 5: 8,754; copy number 6: 2,422; copy number 7: 14; copy number 8: 2,524.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,538 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–248,937,043, 2,524 genes, copy number 8 (broad region; genes not listed).
- chr2:89,906,757–89,916,052, 2 genes, copy number 7: IGKV3D-34, IGKV1D-33.
- chr2:90,179,889–90,367,699, 9 genes, copy number 7: IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr5:795,606–892,801, 3 genes, copy number 7 (within-gene range 6–7): ZDHHC11, SPCS2P3, BRD9.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
